Somatic mutation profile of tumor specimen TCGA-D3-A3CB-06A (aliquot TCGA-D3-A3CB-06A-11D-A196-08) from TCGA case TCGA-D3-A3CB, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 46.9 years (17,125 days).
Specimen TCGA-D3-A3CB-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1ef4e3b7-eefc-4a48-a244-ffd9a75be3af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A3CB-10A (Blood Derived Normal), aliquot TCGA-D3-A3CB-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23f289c7-10ba-4ede-bb52-749dbdb06753

The open-access MAF lists 270 somatic variants for this specimen: 173 protein-altering or splice-affecting, 88 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 88, Nonsense Mutation 10, Intron 4, RNA 3, Splice Region 3, Frame Shift Del 2, Splice Site 2, In Frame Del 1, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CDKN2A | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 13/118 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.665); catalogued as CM034218, CM095540, COSV58683071, COSV58683670; called by muse, mutect2, varscan2
- GRIN2A | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1555491648, CM138230, COSV58019167, COSV58047483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.2845C>T p.P949S | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60912507; called by muse, mutect2, varscan2
- ADGRG4 | c.3037C>T p.H1013Y | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV54951809; called by muse, mutect2, varscan2
- AKAP6 | c.6332C>T p.S2111L | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773070431, COSV55206503; called by mutect2, varscan2
- AL049569.3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | PolyPhen possibly damaging (0.81); catalogued as COSV58699064; called by muse, mutect2, varscan2
- ALOX12B | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV59871708; called by muse, mutect2, varscan2
- AP3S1 | c.391G>A p.E131K | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV57473724, COSV99061862; called by muse, varscan2
- ARID5B | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs374377066, COSV54429955; called by muse, mutect2, varscan2
- ARSJ | c.830G>A p.R277K | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV59536886, COSV59537108; called by muse, mutect2
- ART3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV61913510; called by mutect2, varscan2
- ASNSD1 | c.1157C>T p.S386F | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.012); catalogued as COSV53623118; called by muse, mutect2, varscan2
- ASTN1 | c.2987G>A p.G996E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62493585; called by muse, mutect2, varscan2
- AZI2 | c.74C>T p.P25L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV55423424; called by muse, mutect2, varscan2
- BRINP1 | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.329); catalogued as COSV56294847; called by muse, mutect2, varscan2
- BUB1B | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV55010718; called by muse, mutect2, varscan2
- C19orf12 | c.413A>G p.N138S (on ENST00000392278 / NM_001031726.3; = p.N127S on NM_031448.6) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV60364343; called by muse, mutect2, varscan2
- CAD | c.1035T>G p.D345E | Missense Mutation (SNP) | VAF 42/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53024681; called by muse, mutect2, varscan2
- CARS1 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.086); catalogued as rs766597408, COSV53451655; called by muse, mutect2, varscan2
- CBLL1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.587); catalogued as COSV56028398; called by muse, mutect2, varscan2
- CCDC141 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs914187336, COSV55370770; called by muse, mutect2, varscan2
- CCDC62 | c.1886C>T p.S629L | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752165996, COSV53431506; called by mutect2, varscan2
- CD101 | c.1864C>T p.R622C | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.828); catalogued as rs1362169599, COSV56716851; called by muse, mutect2, varscan2
- CDH9 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258336; called by mutect2, varscan2
- CDHR2 | c.2503G>A p.D835N | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56135997; called by muse, mutect2, varscan2
- CEACAM7 | c.649G>A p.E217K | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV50072597; called by muse, varscan2
- CELSR3 | c.5380C>T p.R1794W | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV50842733; called by muse, mutect2, varscan2
- CERS3 | c.838C>T p.P280S | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867892206, COSV52566117; called by muse, mutect2, varscan2
- CES3 | c.820-1G>A p.X274_splice | Splice Site (SNP) | VAF 5/47 reads (11%) | catalogued as COSV57592918; called by muse, mutect2
- CFAP45 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs756128446, COSV63648426; called by muse, mutect2, varscan2
- CFAP57 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs902787951, COSV100764007; called by muse, varscan2
- CFAP57 | c.1153T>A p.Y385N | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100764008; called by muse, varscan2
- CFAP92 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 22/111 reads (20%) | catalogued as COSV54046683; called by muse, mutect2, varscan2
- CHERP | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.686); catalogued as COSV52223123; called by muse, mutect2, varscan2
- CHGB | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66759868; called by muse, mutect2, varscan2
- CLUL1 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV58111559; called by mutect2, varscan2
- CNGA4 | c.63G>A p.R21= | Splice Region (SNP) | VAF 43/211 reads (20%) | catalogued as rs1442671464, COSV56410229; called by muse, mutect2, varscan2
- CNNM4 | c.1813C>T p.R605* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as rs1021713187, CM090738, COSV65660159; called by muse, mutect2
- COL7A1 | c.1289C>T p.S430F | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.859); catalogued as COSV60392858; called by muse, mutect2, varscan2
- CSMD2 | c.3854C>T p.S1285L | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53890457, COSV99595169; called by muse, mutect2, varscan2
- CSMD2 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.531); catalogued as rs1172743824, COSV53890468; called by mutect2, varscan2
- CSNK1G1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 14/58 reads (24%) | catalogued as COSV57307612; called by muse, mutect2, varscan2
- CYBB | c.1598G>A p.G533E | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD106292, COSV66085006; called by muse, mutect2, varscan2
- CYP21A2 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV64475623; called by muse, mutect2, varscan2
- DCC | c.3986G>A p.R1329K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.63); catalogued as COSV71428594; called by muse, mutect2
- DENND2B | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV58202104; called by muse, mutect2, varscan2
- DIP2B | c.832C>T p.Q278* | Nonsense Mutation (SNP) | VAF 9/84 reads (11%) | catalogued as COSV56580705; called by muse, mutect2
- DLGAP4 | c.215C>T p.P72L | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59415641, COSV59419712; called by muse, mutect2, varscan2
- DNAH3 | c.10381C>T p.P3461S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1050992280, COSV54505347; called by muse, varscan2
- DNAH7 | c.5338G>A p.E1780K | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1371123844, COSV56756387; called by muse, mutect2, varscan2
- EIF3F | c.523A>C p.T175P | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59141593; called by muse, mutect2
- ENAM | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV104432419, COSV68535486; called by muse, mutect2, varscan2
- EPHA6 | c.2900G>A p.G967E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67564023; called by muse, mutect2, varscan2
- F13B | c.1630G>A p.E544K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as COSV66372835; called by mutect2, varscan2
- FAM160A2 | c.2335C>T p.R779C (on ENST00000449352 / NM_001098794.2; = p.R793C on NM_032127.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56410225; called by mutect2, varscan2
- FGF13 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 27/72 reads (38%) | catalogued as COSV59543850; called by muse, mutect2, varscan2
- FSHR | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV58619851; called by muse, mutect2, varscan2
- FSIP2 | c.16760C>T p.S5587L | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs1485710684, COSV58081199; called by muse, mutect2, varscan2
- FSTL5 | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.925); catalogued as COSV60185507; called by muse, mutect2
- FUBP3 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as COSV60513410; called by muse, mutect2, varscan2
- FUT8 | c.1471C>T p.H491Y (on ENST00000360689 / NM_001371534.1; = p.H328Y on NM_004480.4) | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61281625; called by muse, mutect2, varscan2
- GALNT13 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.91); catalogued as rs148805770; called by mutect2, varscan2
- GCFC2 | c.561G>C p.K187N | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV58080128; called by muse, mutect2, varscan2
- GFRAL | c.1122-1G>A p.X374_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | catalogued as COSV61229627; called by muse, mutect2, varscan2
- GPR137C | c.850G>A p.D284N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs757031023, COSV58704474; called by muse, mutect2, varscan2
- GRM8 | c.2635G>A p.G879S | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.443); catalogued as COSV58811484; called by muse, mutect2, varscan2
- H2AX | c.353C>T p.P118L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as COSV53827886; called by muse, mutect2, varscan2
- HMCN1 | c.11932C>T p.R3978* | Nonsense Mutation (SNP) | VAF 36/119 reads (30%) | catalogued as rs999852853, COSV54885466; called by muse, mutect2, varscan2
- IFNA5 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV52386323; called by muse, mutect2, varscan2
- IGKV1-17 | c.160G>A p.D54N | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs549645121; called by muse, mutect2, varscan2
- INSL6 | c.152G>A p.S51N | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as rs1032405198, COSV67562575; called by muse, mutect2
- KCNA6 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1239473214, COSV54974483; called by muse, mutect2, varscan2
- KCNE2 | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 79/350 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.129); catalogued as COSV51709991; called by muse, mutect2, varscan2
- KCNH5 | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.027); catalogued as COSV59755173; called by muse, mutect2, varscan2
- KCNK10 | c.1471G>A p.E491K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56640972; called by muse, mutect2
- KCNQ5 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as COSV59653515; called by mutect2, varscan2
- KL | c.2800C>T p.Q934* | Nonsense Mutation (SNP) | VAF 18/120 reads (15%) | catalogued as COSV66308175; called by mutect2, varscan2
- KRT28 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as COSV60684033; called by muse, mutect2, varscan2
- KRT34 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101222690; called by muse, mutect2
- LARGE1 | c.233C>T p.A78V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.057); catalogued as COSV61659304; called by muse, mutect2, varscan2
- LARP4 | c.1453C>T p.P485S | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53320983; called by muse, mutect2
- LIMCH1 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV58277483; called by muse, mutect2
- LMNTD1 | c.581C>T p.P194L | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51445377; called by muse, mutect2, varscan2
- LRTM2 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.207); catalogued as rs769299567, COSV54564320; called by mutect2, varscan2
- MAST4 | c.1977G>A p.M659I (on ENST00000403625 / NM_001164664.2; = p.M470I on NM_015183.3) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.192); catalogued as COSV55119092; called by muse, mutect2, varscan2
- MCTP2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.985); catalogued as rs1425029188, COSV59142077; called by muse, mutect2, varscan2
- MFSD1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 40/209 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51839698; called by muse, mutect2, varscan2
- MOGAT2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as COSV52218724; called by muse, varscan2
- MORN1 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV66004569; called by muse, mutect2, varscan2
- MPP5 | c.16A>C p.M6L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV55528432; called by muse, mutect2
- MSTO1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 29/82 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as rs761740567, COSV55471494; called by muse, mutect2, varscan2
- MUC16 | c.39207G>A p.R13069= | Splice Region (SNP) | VAF 10/76 reads (13%) | catalogued as rs201227978, COSV66690503, COSV66692656; called by mutect2, varscan2
- MUC16 | c.19295C>T p.S6432F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.905); catalogued as COSV67453173; called by muse, mutect2, varscan2
- MUC16 | c.15032C>T p.S5011L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.205); catalogued as COSV67453182; called by mutect2, varscan2
- MUC17 | c.6839C>T p.P2280L | Missense Mutation (SNP) | VAF 72/228 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV60281768; called by muse, mutect2, varscan2
- MYH1 | c.5557G>A p.E1853K | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56845225; called by muse, mutect2
- NBEA | c.8086G>A p.G2696R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100078944, COSV59768287; called by muse, mutect2, varscan2
- NDC80 | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV55247374; called by muse, mutect2, varscan2
- NEK5 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV62879266; called by muse, varscan2
- NLRP8 | c.2021C>A p.S674Y | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV52584797; called by mutect2, varscan2
- NOL8 | c.1763C>T p.S588F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as rs769968828, COSV62634618; called by mutect2, varscan2
- OASL | c.1453G>A p.D485N | Missense Mutation (SNP) | VAF 40/357 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV56566591; called by muse, mutect2, varscan2
- OR10A5 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55053516; called by muse, mutect2, varscan2
- OR13C3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV66165698; called by muse, mutect2, varscan2
- OR1L3 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59169405; called by muse, varscan2
- OR1L8 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.452); catalogued as COSV59186034, COSV59187614; called by muse, mutect2
- OR2M3 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71758938; called by muse, mutect2, varscan2
- OR4K5 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV60002682; called by muse, mutect2, varscan2
- OR51T1 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs760343102, COSV59024300; called by muse, mutect2, varscan2
- OR5AS1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57981179, COSV57982861; called by muse, mutect2, varscan2
- OR6V1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV69237033; called by muse, mutect2
- PCDHA7 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.079); catalogued as COSV65342777; called by muse, mutect2, varscan2
- PDCD2L | c.538C>T p.P180S | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1205635021, COSV99875074; called by muse, mutect2
- PLBD1 | c.676G>A p.G226R | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53692323; called by muse, mutect2, varscan2
- PLEKHA7 | c.1952C>T p.S651L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.306); catalogued as rs765459832, COSV63044509; called by muse, mutect2, varscan2
- PLEKHA7 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as COSV100850280, COSV63044519; called by muse, mutect2, varscan2
- PPFIA4 | c.3113T>C p.V1038A (on ENST00000447715; = p.V1039A on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV55312853; called by muse, mutect2
- PPP1R12B | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs755584686, COSV61114472; called by muse, mutect2, varscan2
- PPP1R42 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV61206906; called by muse, mutect2
- PROS1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV62397979; called by muse, mutect2
- PRSS1 | c.436A>T p.N146Y | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV61191556; called by muse, mutect2, varscan2
- PTCRA | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58975451; called by muse, mutect2, varscan2
- PTK6 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV53916173; called by muse, mutect2
- PTPRN | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV55346441; called by muse, mutect2, varscan2
- PTPRT | c.3718C>T p.H1240Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100629067; called by muse, mutect2, varscan2
- PYHIN1 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.189); catalogued as COSV63721809; called by muse, mutect2
- RAB41 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.007); catalogued as rs746401277, COSV52103470; called by mutect2, varscan2
- RABGEF1 | c.788C>T p.P263L (on ENST00000439720 / NM_001287061.2; = p.P250L on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.055); catalogued as COSV53161360; called by muse, mutect2
- RBM25 | c.2041C>A p.P681T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.027); catalogued as COSV56199013; called by muse, mutect2, varscan2
- RGN | c.696G>A p.G232= | Splice Region (SNP) | VAF 4/15 reads (27%) | catalogued as COSV60275851; called by muse, mutect2, varscan2
- RNF146 | c.804_806del p.E268del (on ENST00000368314 / NM_001242850.2; = p.E267del on NM_030963.3 and 2 other RefSeq transcripts) | In Frame Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs760706934; called by pindel, varscan2
- RYR3 | c.11164G>A p.E3722K (on ENST00000389232; = p.E3723K on NM_001036.6) | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.426); catalogued as COSV66781862; called by mutect2, varscan2
- SALL1 | c.3358C>T p.P1120S | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV99176910; called by mutect2, varscan2
- SH3TC1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.96); PolyPhen benign (0.006); catalogued as rs1399657135, COSV55282366; called by muse, mutect2
- SHISAL2A | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV68979478; called by muse, mutect2, varscan2
- SIM1 | c.1982C>T p.P661L | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV53489965; called by muse, mutect2
- SIPA1L3 | c.2969T>C p.V990A | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55910661; called by muse, mutect2
- SLC25A19 | c.236G>A p.W79* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | catalogued as COSV57467247; called by muse, mutect2, varscan2
- SLC6A12 | c.852G>A p.W284* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV62884268; called by muse, mutect2
- SLC6A13 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.296); catalogued as COSV58256011; called by muse, mutect2, varscan2
- SLC6A14 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371749747, COSV64145993; called by muse, mutect2, varscan2
- SLCO5A1 | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 78/231 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867414896, COSV52652993, COSV52663499; called by muse, mutect2, varscan2
- SMARCA5 | c.2692G>A p.E898K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV51642932; called by muse, mutect2, varscan2
- SPOPL | c.1064G>T p.G355V | Missense Mutation (SNP) | VAF 31/272 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54512432; called by mutect2, varscan2
- SYT14 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as rs140554266; called by mutect2, varscan2
- THSD7B | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV55665012; called by muse, varscan2
- THSD7B | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1245164296, COSV55665029, COSV99748271; called by muse, varscan2
- TIMM50 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58679012; called by muse, mutect2, varscan2
- TLR5 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60558213, COSV60560154; called by muse, mutect2, varscan2
- TMC5 | c.2209C>T p.L737F (on ENST00000396229 / NM_001105248.1; = p.L491F on NM_024780.5) | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs969659312, COSV54901756; called by muse, mutect2, varscan2
- TMEM132B | c.1100G>A p.G367E | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV54748019; called by muse, mutect2
- TPGS2 | c.201C>A p.N67K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.63); catalogued as COSV100528881; called by muse, mutect2
- TPGS2 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as COSV100528883; called by muse, mutect2
- TREML1 | c.764G>A p.G255E | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.061); catalogued as COSV64191062; called by muse, mutect2, varscan2
- TRIM15 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64989164; called by muse, mutect2, varscan2
- TRPV2 | c.1882G>C p.A628P | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV58427697; called by muse, mutect2
- TTN | c.59576G>A p.W19859* (on ENST00000591111; = p.W12435* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | catalogued as COSV59941411; called by muse, mutect2, varscan2
- UNC79 | c.7639G>A p.E2547K (on ENST00000393151 / NM_001346218.2; = p.E2370K on NM_020818.5) | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV56379059; called by muse, mutect2
- WASHC2C | c.1789G>A p.A597T | Missense Mutation (SNP) | VAF 24/240 reads (10%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV60490546, COSV60491545; called by muse, mutect2, varscan2
- XDH | c.3496G>A p.D1166N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1159401289, COSV65147558; called by mutect2, varscan2
- YLPM1 | c.1607C>T p.P536L | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV53108321; called by muse, mutect2, varscan2
- ZNF106 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 24/208 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1418539913, COSV55514677; called by muse, mutect2, varscan2
- ZNF226 | c.1568T>G p.V523G | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV56196221; called by muse, mutect2, varscan2
- ZNF280C | c.971T>C p.V324A | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV63968669; called by muse, mutect2
- ZNF354B | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV59365458; called by mutect2, varscan2
- FYB2 | c.539_542delinsGAG p.E180Gfs*37 | Frame Shift Del (DEL) | VAF 21/79 reads (27%) | called by pindel, varscan2*
- HDAC4 | c.1486del p.Q496Sfs*9 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, varscan2
- IGHV1-58 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- NBPF15 | c.1760C>T p.P587L | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PITRM1 | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.346); called by muse, mutect2
- TRAV18 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TRDV1 | c.195G>A p.M65I | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.277); called by mutect2, varscan2
- A1BG | c.730C>A p.R244= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs145532647, COSV99568508; called by muse, varscan2
- ADCK2 | c.987G>A p.K329= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV50780888; called by muse, mutect2, varscan2
- AK7 | c.897G>A p.G299= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs140878553; called by muse, mutect2, varscan2
- ALDH1B1 | c.75C>T p.L25= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs775145119, COSV66619412; called by muse, mutect2, varscan2
- ANGPTL5 | c.1062T>A p.L354= | Silent (SNP) | VAF 27/118 reads (23%) | catalogued as COSV57532274; called by muse, mutect2, varscan2
- AP002748.5 | c.565C>T p.L189= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV59147551; called by muse, mutect2, varscan2
- ARAP2 | c.2205C>T p.S735= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV58284208; called by muse, mutect2
- BNC1 | c.1407C>T p.F469= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV61756876; called by muse, mutect2, varscan2
- C2CD3 | c.3291C>T p.F1097= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV58091116, COSV58101522; called by muse, mutect2, varscan2
- CACNA1A | c.1101G>A p.R367= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as COSV100800320, COSV64192706; called by muse, mutect2, varscan2
- CACNA1D | c.2097C>T p.F699= (on ENST00000350061 / NM_001128840.3; = p.F719= on NM_000720.4) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV55441082; called by mutect2, varscan2
- CACNG3 | c.156G>A p.R52= | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1230597836, COSV50064880; called by muse, mutect2, varscan2
- CDH18 | c.1935C>T p.I645= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as COSV56909090; called by muse, mutect2, varscan2
- CDKN2A | c.261G>A p.R87= | Silent (SNP) | VAF 12/117 reads (10%) | catalogued as rs546300971, COSV58701366; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CERS2 | c.618C>T p.F206= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV54978730; called by muse, mutect2, varscan2
- CHURC1-FNTB | c.276C>T p.V92= | Silent (SNP) | VAF 24/184 reads (13%) | catalogued as COSV55760440; called by muse, varscan2
- COL1A1 | c.3984G>A p.E1328= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as COSV56803221; called by muse, mutect2
- CWC22 | c.2322T>C p.G774= | Silent (SNP) | VAF 28/169 reads (17%) | catalogued as rs767958661, COSV55427418; called by muse, varscan2
- CYLC2 | c.375G>A p.K125= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV66336607; called by muse, mutect2, varscan2
- CYP4X1 | c.984C>T p.I328= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs991608173, COSV100903316, COSV64150016; called by muse, mutect2, varscan2
- DENND1A | c.261C>T p.C87= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs1185740270, COSV65323657; called by muse, mutect2, varscan2
- DLGAP2 | c.2763C>T p.F921= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV70096091; called by muse, mutect2, varscan2
- DNAH5 | c.5589C>T p.F1863= | Silent (SNP) | VAF 9/55 reads (16%) | catalogued as COSV54211810; called by muse, mutect2, varscan2
- DYNC1H1 | c.8169C>T p.L2723= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV64135150; called by muse, mutect2, varscan2
- ERICH3 | c.1230G>A p.P410= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs375773806; called by mutect2, varscan2
- FBXO43 | c.1212C>T p.H404= | Silent (SNP) | VAF 22/171 reads (13%) | catalogued as COSV101413902, COSV71053561; called by muse, mutect2, varscan2
- FHDC1 | c.2478C>T p.S826= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs573487679, COSV52598536; called by muse, mutect2, varscan2
- FLG2 | c.6303G>A p.R2101= | Silent (SNP) | VAF 90/336 reads (27%) | catalogued as COSV66167286; called by muse, varscan2
- FLRT3 | c.1554G>A p.E518= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53958870; called by muse, mutect2, varscan2
- GPATCH8 | c.3765C>T p.S1255= | Silent (SNP) | VAF 17/140 reads (12%) | catalogued as COSV59193706; called by muse, mutect2, varscan2
- GRIN2A | c.3316C>T p.L1106= | Silent (SNP) | VAF 8/148 reads (5%) | catalogued as COSV58025260, COSV58061102; called by muse, mutect2
- HNRNPM | c.762C>T p.S254= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV57691932; called by muse, mutect2, varscan2
- IGHV4-31 | c.228G>A p.G76= | Silent (SNP) | VAF 11/136 reads (8%) | catalogued as rs1380171010, rs569470560; called by muse, mutect2
- INHBB | c.822C>T p.P274= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV54677519; called by muse, mutect2
- KCNJ6 | c.153G>A p.R51= | Silent (SNP) | VAF 13/127 reads (10%) | catalogued as COSV55710926; called by muse, mutect2, varscan2
- KIF15 | c.3282C>T p.T1094= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1434663095, COSV58159208; called by muse, mutect2
- KIF1A | c.279C>T p.I93= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV57485087; called by muse, mutect2
- KRT16 | c.282C>T p.F94= | Silent (SNP) | VAF 8/29 reads (28%) | catalogued as rs570977410, COSV56967350; called by mutect2, varscan2
- KRT34 | c.969C>T p.A323= | Silent (SNP) | VAF 6/78 reads (8%) | catalogued as COSV67449463; called by muse, mutect2
- KRT34 | c.357G>A p.L119= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV101222691; called by mutect2, varscan2
- KRT76 | c.1233A>T p.L411= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV60119515; called by muse, mutect2
- LCT | c.2100C>T p.I700= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV51545766; called by muse, mutect2, varscan2
- MAB21L2 | c.765G>A p.K255= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV58261096; called by muse, mutect2, varscan2
- MAT1A | c.111C>T p.I37= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV64745006; called by mutect2, varscan2
- MAT2A | c.999C>T p.F333= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV52087401; called by muse, mutect2, varscan2
- MTTP | c.2583C>T p.S861= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs773035173, COSV55504564; called by mutect2, varscan2
- MYH13 | c.1809G>T p.L603= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV52822888; called by mutect2, varscan2
- MYH4 | c.1143G>A p.T381= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs1458185288, COSV55114336, COSV55123768; called by muse, mutect2, varscan2
- MYO5C | c.4578C>T p.S1526= | Silent (SNP) | VAF 19/115 reads (17%) | catalogued as rs761120987, COSV55903838; called by muse, mutect2, varscan2
- NPAP1 | c.984G>A p.R328= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as COSV100276366, COSV61505370; called by muse, varscan2
- NPTX2 | c.720C>T p.I240= | Silent (SNP) | VAF 38/152 reads (25%) | catalogued as COSV55716553; called by muse, mutect2, varscan2
- NRP2 | c.2319G>A p.E773= | Silent (SNP) | VAF 17/197 reads (9%) | catalogued as COSV55925388; called by muse, mutect2
- OR10H2 | c.213C>T p.I71= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV59945592; called by muse, mutect2
- OR10H5 | c.93C>T p.F31= | Silent (SNP) | VAF 12/162 reads (7%) | catalogued as COSV58277671; called by muse, mutect2
- OR13C4 | c.339C>T p.F113= | Silent (SNP) | VAF 10/95 reads (11%) | catalogued as rs749736712, COSV52925949, COSV52926506; called by mutect2, varscan2
- OR2T2 | c.39C>T p.F13= | Silent (SNP) | VAF 20/158 reads (13%) | catalogued as rs779374477, COSV61617823; called by muse, mutect2, varscan2
- OR5AS1 | c.903C>T p.L301= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1289584129, COSV57981185; called by mutect2, varscan2
- OR5H6 | c.828G>A p.L276= (on ENST00000642105; = p.L260= on NM_001005479.2) | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs748325053, COSV67351191; called by muse, mutect2, varscan2
- OR8H3 | c.279C>T p.S93= | Silent (SNP) | VAF 56/286 reads (20%) | catalogued as COSV57907896; called by muse, varscan2
- P2RY10 | c.264C>T p.P88= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV50680605, COSV99409459; called by muse, varscan2
- PAK5 | c.186C>T p.I62= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV62023494, COSV62023892; called by muse, mutect2, varscan2
- PAPPA | c.3669T>G p.A1223= | Silent (SNP) | VAF 15/103 reads (15%) | catalogued as COSV60279265; called by muse, mutect2, varscan2
- PASK | c.1431C>T p.L477= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV52150119; called by muse, mutect2, varscan2
- PCDH9 | c.3177C>T p.S1059= (on ENST00000377865 / NM_203487.3; = p.S1025= on NM_020403.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2, varscan2
- PCDHA8 | c.270C>T p.I90= | Silent (SNP) | VAF 30/200 reads (15%) | catalogued as rs1554138327, COSV65335369; called by muse, mutect2, varscan2
- PCDHB10 | c.1173C>T p.F391= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs139481353; called by muse, mutect2, varscan2
- PIEZO2 | c.8232C>T p.I2744= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV53287456; called by mutect2, varscan2
- PRUNE2 | c.216G>A p.T72= | Silent (SNP) | VAF 18/170 reads (11%) | catalogued as rs142442874, COSV65026783; called by mutect2, varscan2
- PSG7 | c.1110G>A p.G370= | Silent (SNP) | VAF 22/184 reads (12%) | catalogued as COSV68444566; called by muse, mutect2, varscan2
- RDH12 | c.753C>T p.F251= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as COSV50821501; called by muse, mutect2
- RSPH14 | c.411G>A p.Q137= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV53267432; called by muse, mutect2
- RYR1 | c.2445C>T p.L815= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs773408738, COSV62092350; called by muse, mutect2, varscan2
- SCN9A | c.2544C>T p.S848= (on ENST00000303354; = p.S837= on NM_002977.3) | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV57603799; called by muse, mutect2, varscan2
- SEL1L3 | c.2538C>T p.I846= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV53537855; called by muse, mutect2, varscan2
- SERPINA3 | c.970C>T p.L324= | Silent (SNP) | VAF 10/68 reads (15%) | catalogued as COSV67585502; called by muse, mutect2, varscan2
- SLC26A5 | c.342C>T p.Y114= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as rs1313565018, COSV59699434; called by muse, mutect2, varscan2
- SLC30A3 | c.219G>A p.R73= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV51984539; called by muse, mutect2, varscan2
- SLC8A1 | c.1989G>A p.K663= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as rs1316235822, COSV60474253; called by muse, mutect2
- SMARCD1 | c.1548G>A p.*516= | Silent (SNP) | VAF 6/54 reads (11%) | catalogued as COSV56547504, COSV99993861; called by muse, mutect2
- SYNE1 | c.15891C>T p.I5297= (on ENST00000367255 / NM_182961.4; = p.I5226= on NM_033071.3) | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as COSV54932625; called by muse, mutect2, varscan2
- TMEM94 | c.1752C>T p.P584= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV58593724; called by muse, mutect2
- TRIM55 | c.832C>T p.L278= | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV52543920, COSV52544557; called by muse, mutect2
- TSPEAR | c.117C>T p.V39= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV59955484; called by muse, mutect2, varscan2
- VPREB1 | c.357C>T p.A119= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- VPS13D | c.5967C>T p.F1989= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as rs1178790625, COSV50626965; called by muse, mutect2, varscan2
- XIRP2 | c.7467G>A p.R2489= (on ENST00000628543; = p.R2664= on NM_152381.6) | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54688488; called by muse, mutect2
- ZNF136 | c.528C>T p.T176= | Silent (SNP) | VAF 4/29 reads (14%) | catalogued as COSV59710392; called by mutect2, varscan2
- ZNF816 | c.160T>C p.L54= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as COSV54410688; called by muse, mutect2, varscan2
- C11orf40 | n.302G>T | RNA (SNP) | VAF 18/109 reads (17%) | catalogued as COSV56890100; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3968C>T | Intron (SNP) | VAF 16/58 reads (28%) | catalogued as rs1375619787, COSV100505443; called by muse, mutect2, varscan2
- CLCA3P | n.498C>T | RNA (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+2646G>A | Intron (SNP) | VAF 48/470 reads (10%) | catalogued as rs1308447361; called by muse, mutect2
- IGHG1 | chr14:105737786 C>T | 3'Flank (SNP) | VAF 7/35 reads (20%) | called by muse, mutect2, varscan2
- MIR1246 | n.15G>A | RNA (SNP) | VAF 26/152 reads (17%) | called by muse, mutect2, varscan2
- NBPF11 | c.-549+2507C>T | Intron (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- OR8A1 | c.-4G>A | 5'UTR (SNP) | VAF 6/40 reads (15%) | catalogued as COSV52508181; called by muse, mutect2
- TTN | c.10360+3906A>C | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV100621947; called by muse, mutect2, varscan2
